Somatic mutation profile of tumor specimen MMRF_1356_1_BM_CD138pos (aliquot MMRF_1356_1_BM_CD138pos_T1_KAS5U_L01212) from MMRF case MMRF_1356, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,706 days).
Specimen MMRF_1356_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c81c34c-0d5c-47ba-86ee-2412455afc77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1356_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1356_1_PB_Whole_C2_KAS5U_L01223; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abf0f2dc-ee18-4710-a229-31105a161df9

The open-access MAF lists 120 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 41, Missense Mutation 40, Silent 18, Intron 10, 5'UTR 4, 3'Flank 3, Splice Site 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BACH1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1046465663, COSV54517507, COSV99728190; called by muse, mutect2, varscan2
- CMYA5 | c.7807G>T p.A2603S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770958823, COSV71409864; called by muse, mutect2, varscan2
- COL6A3 | c.8431C>T p.R2811C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371361651; called by muse, mutect2, varscan2
- DSC2 | c.1648C>A p.L550I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV51866560; called by muse, mutect2, varscan2
- FAM135A | c.2981G>A p.R994K (on ENST00000370479 / NM_001351599.1; = p.R781K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52060486; called by muse, mutect2, varscan2
- HECW1 | c.3971C>T p.T1324M | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772206662; called by muse, mutect2, varscan2
- IGHV2-70 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs371189824; called by muse, mutect2, varscan2
- IGLV2-11 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.235); catalogued as rs1265423270; called by muse, varscan2
- ILF3 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs914167445, COSV51556389; called by muse, mutect2, varscan2
- ITGA7 | c.2987G>A p.R996Q (on ENST00000555728; = p.R952Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs753351732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD9 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99301969; called by muse, varscan2
- MMP2 | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1397358458; called by muse, mutect2, varscan2
- NGFR | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as rs752053070, COSV50803523; called by muse, mutect2, varscan2
- PTPRK | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs141536662; called by muse, mutect2, varscan2
- SCUBE2 | c.2176C>T p.L726= (on ENST00000649792 / NM_001367977.2; = p.L669= on NM_020974.3) | Splice Region (SNP) | VAF 20/48 reads (42%) | catalogued as rs777039755; called by muse, mutect2, varscan2
- TLR4 | c.1273G>A p.E425K (on ENST00000355622 / NM_138554.5; = p.E385K on NM_003266.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs1462969834; called by muse, mutect2, varscan2
- TNK2 | c.3005G>T p.G1002V | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761374258; called by muse, mutect2, varscan2
- ZFHX2 | c.2800G>A p.G934R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.12); catalogued as rs1412523842; called by muse, mutect2, varscan2
- CACNA1G | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- CARMIL1 | c.72A>G p.I24M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2
- CCDC88A | c.2710T>G p.L904V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKL4 | c.927+1G>A p.X309_splice (on ENST00000395035 / NM_001346911.1; = p.V310I on NM_001009565.2) | Splice Site (SNP) | VAF 85/190 reads (45%) | called by muse, mutect2, varscan2
- CHEK1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CREBZF | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DACH2 | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DCAF8L2 | c.951C>A p.H317Q | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DDX17 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.5093C>T p.S1698L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRS2 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- HAS1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HK1 | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IGLC2 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV2-11 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, varscan2
- MAX | c.233del p.N78Tfs*92 | Frame Shift Del (DEL) | VAF 100/135 reads (74%) | called by mutect2, pindel, varscan2
- MUC5AC | c.15095T>C p.I5032T | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYORG | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RNF180 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SGSM1 | c.1935+2T>C p.X645_splice | Splice Site (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- SPG11 | c.7021T>G p.Y2341D | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM132C | c.1931T>A p.V644E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TMEM30A | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPRG1 | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNIP | c.724A>T p.I242F | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM19 | c.1788C>A p.I596= | Silent (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- CLASP2 | c.487C>T p.L163= | Silent (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- GALNT17 | c.226C>A p.R76= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- GDF6 | c.1215G>A p.T405= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV54624173; called by muse, mutect2, varscan2
- GRID2IP | c.2211C>T p.G737= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- HCAR2 | c.1020C>T p.G340= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as rs200668464, COSV61025017; called by muse, mutect2, varscan2
- IGLV2-11 | c.129A>G p.G43= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs762371007; called by muse, varscan2
- IGLV2-11 | c.294G>A p.G98= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs757857348; called by muse, varscan2
- KDM2A | c.2865C>G p.V955= | Silent (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- MNDA | c.942G>A p.K314= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs1324222610; called by muse, mutect2, varscan2
- MRTFB | c.543T>A p.T181= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- PRRC2C | c.5979A>G p.L1993= (on ENST00000367742; = p.L1991= on NM_015172.4) | Silent (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- SCAMP3 | c.915C>T p.R305= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as rs760695138; called by muse, mutect2, varscan2
- SEL1L3 | c.519A>T p.V173= | Silent (SNP) | VAF 73/165 reads (44%) | called by muse, mutect2, varscan2
- TIFA | c.69T>G p.P23= | Silent (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- TMIGD1 | c.261C>T p.V87= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV61028669; called by muse, mutect2, varscan2
- TNS1 | c.1680C>T p.P560= | Silent (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- XKR9 | c.960T>C p.P320= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV68773143; called by muse, mutect2, varscan2
- ADCY8 | c.*52A>T | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- AKT1S1 | c.-7-1941G>A | Intron (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- ANKRD28 | c.-21G>A | 5'UTR (SNP) | VAF 65/111 reads (59%) | called by muse, mutect2, varscan2
- ANOS1 | c.*3801G>T | 3'UTR (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
- AP1S2 | c.*525T>A | 3'UTR (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- ARMC10 | c.*576A>T | 3'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- ARNTL2 | chr12:27423263 T>G | 3'Flank (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2
- ATP1B3 | c.*659T>A | 3'UTR (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- ATP6V1C2 | c.*628G>A | 3'UTR (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- BNC1 | c.*1090G>A | 3'UTR (SNP) | VAF 27/47 reads (57%) | catalogued as rs957515618; called by muse, mutect2, varscan2
- CALB1 | c.*956C>A | 3'UTR (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- CCDC88C | c.271-19130T>C | Intron (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- CHAMP1 | c.*388T>G | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- COBL | c.*666C>T | 3'UTR (SNP) | VAF 34/66 reads (52%) | catalogued as rs759102489; called by muse, mutect2, varscan2
- CTR9 | c.-95_-71del | 5'UTR (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- DERL2 | c.*1963T>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- GABRA6 | c.*310G>C | 3'UTR (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- GPLD1 | c.*282C>T | 3'UTR (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- GUF1 | c.*1733A>G | 3'UTR (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- IAPP | c.*1259G>A | 3'UTR (SNP) | VAF 29/39 reads (74%) | called by muse, mutect2, varscan2
- ICE1 | c.-127G>A | 5'UTR (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- IKZF3 | c.*2170T>A | 3'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- KBTBD8 | c.*773C>T | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- KIF14 | c.*1222_*1223del | 3'UTR (DEL) | VAF 4/53 reads (8%) | called by pindel, varscan2
- LEPR | c.*2276G>A | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- LPL | c.89-1532C>T | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs1015143398; called by muse, mutect2, varscan2
- LRRC17 | c.*207A>T | 3'UTR (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- LRRC49 | c.500+3166C>T | Intron (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- LRRC7 | c.647+35619A>G | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- MCU | c.150+617T>C | Intron (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2
- MEF2A | c.*2725T>C | 3'UTR (SNP) | VAF 68/116 reads (59%) | called by muse, mutect2, varscan2
- MTFR1 | c.*653C>T | 3'UTR (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- MYCBP2 | c.*402A>G | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- NEURL1B | c.*4587_*4604delinsATACAACTTTGGCTTGTT | 3'UTR (ONP) | VAF 7/29 reads (24%) | called by pindel, varscan2*
- OR9Q1 | c.-15+53058C>T | Intron (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- ORAI3 | chr16:30956334 C>T | 3'Flank (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- PCDH17 | c.*1785C>T | 3'UTR (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- PDE3A | c.*45_*46dup | 3'UTR (INS) | VAF 87/209 reads (42%) | called by mutect2, pindel, varscan2
- PLA2G2C | c.*1339A>C | 3'UTR (SNP) | VAF 42/69 reads (61%) | called by muse, mutect2, varscan2
- POLR1E | c.*36C>T | 3'UTR (SNP) | VAF 44/98 reads (45%) | catalogued as COSV66773024; called by muse, mutect2, varscan2
- PPFIA4 | c.*1846T>C | 3'UTR (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- PREX2 | c.*2118T>C | 3'UTR (SNP) | VAF 45/74 reads (61%) | called by muse, mutect2, varscan2
- PRLR | c.*319T>C | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- PTK2B | c.2548+146_2548+166del | Intron (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- RAB6B | c.*371_*374del | 3'UTR (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- RAG1 | c.*2521T>C | 3'UTR (SNP) | VAF 18/36 reads (50%) | catalogued as rs957828543; called by muse, varscan2
- SH3BGRL2 | c.*983C>A | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- SLC35B4 | c.*3656G>A | 3'UTR (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- SOSTDC1 | c.*398del | 3'UTR (DEL) | VAF 16/30 reads (53%) | called by mutect2, varscan2
- SSU72 | c.364+224G>A | Intron (SNP) | VAF 22/99 reads (22%) | catalogued as rs936803538; called by muse, mutect2, varscan2
- STMND1 | c.*10dup | 3'UTR (INS) | VAF 40/79 reads (51%) | catalogued as rs755628023; called by mutect2, pindel, varscan2
- STRN3 | c.*735C>T | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- TIAL1 | chr10:119574785 G>A | 3'Flank (SNP) | VAF 5/14 reads (36%) | catalogued as rs372483277; called by muse, mutect2, varscan2
- TOR1A | c.*373G>A | 3'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- UNC5D | c.*2990T>G | 3'UTR (SNP) | VAF 9/20 reads (45%) | catalogued as COSV54783032; called by muse, mutect2, varscan2
- ZNF134 | c.-36G>A | 5'UTR (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- ZNF354C | c.*2126C>G | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+10333A>T | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
